Somatic mutation profile of tumor specimen TCGA-EL-A3GQ-01A (aliquot TCGA-EL-A3GQ-01A-11D-A202-08) from TCGA case TCGA-EL-A3GQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 72.5 years (26,478 days).
Specimen TCGA-EL-A3GQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a432c51f-0ea2-43a9-941a-d82a9c02ebca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GQ-10A (Blood Derived Normal), aliquot TCGA-EL-A3GQ-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64a7b226-199d-47d0-9660-d544564e7d6e

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADAM8 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV69864642; called by muse, mutect2, varscan2
- DDX39A | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as rs374281705; called by muse, mutect2, varscan2
- GRIN2A | c.1849G>T p.V617L | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58022081, COSV58032220; called by muse, mutect2, varscan2
- KRTAP9-3 | c.238T>G p.C80G | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); catalogued as COSV68616516; called by muse, mutect2, varscan2
- LAMB1 | c.2891G>A p.G964D | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55964394; called by muse, mutect2
- SENP6 | c.1619C>G p.T540R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1399240014, COSV100519666, COSV59191091; called by muse, mutect2, varscan2
- SERPINH1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as rs908092360, COSV63998016; called by muse, mutect2, varscan2
- SLC5A5 | c.1742C>G p.A581G | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55832983; called by muse, mutect2, varscan2
- VTN | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.057); catalogued as COSV56873513; called by muse, mutect2, varscan2
- MED31 | c.106+2dup | Splice Region (INS) | VAF 24/192 reads (13%) | called by mutect2, varscan2
- CCDC88C | c.3387C>T p.S1129= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as rs770294143, COSV66237850; called by muse, mutect2, varscan2
- GPR174 | c.291G>A p.L97= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs1283607805, COSV52132384; called by muse, mutect2, varscan2
- RNFT1 | c.882A>G p.Q294= | Silent (SNP) | VAF 40/85 reads (47%) | catalogued as COSV59869733; called by muse, mutect2, varscan2
- SEC22C | c.673C>T p.L225= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV52565234; called by muse, mutect2, varscan2
